Gene-level copy-number profile of tumor specimen ALCH-B766-TTP1-A from ALCHEMIST case ALCH-B766, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,060 days).
Specimen ALCH-B766-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0786f400-152e-4ad8-b097-7e95678ffa1d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B766-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/9df5cf91-ff31-4c35-8da8-d6d4783490b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,501; copy number 2: 37,325; copy number 3: 14,448; copy number 4: 2,532; copy number 5: 803; copy number 6: 492; copy number 7: 227; copy number 8: 18; copy number 9: 36.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:181,301,967–181,342,213, 4 genes: RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr19:44,905,791–44,919,349, 3 genes: APOE, AC011481.3, APOC1.
- chr22:45,875,999–45,891,438, 1 gene (within-gene range 0–1): BX324167.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,575 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:136,969,200–139,628,434, 68 genes, copy number 5 (broad region; genes not listed).
- chr5:140,157,319–144,170,714, 167 genes, copy number 5 (broad region; genes not listed).
- chr5:149,492,982–149,551,471, 3 genes, copy number 6: CSNK1A1, AC021078.1, RPL29P14.
- chr5:181,040,225–181,295,572, 23 genes, copy number 5: BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5.
- chr6:60,281,444–60,546,660, 1 gene, copy number 6: AC244258.1.
- chr11:94,706,431–98,683,735, 47 genes, copy number 5–8 (within-gene range 3–8): AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1, LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1.
- chr11:101,451,564–101,872,562, 1 gene, copy number 5 (within-gene range 3–5): TRPC6.
- chr11:101,765,935–104,969,366, 60 genes, copy number 5: AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4.
- chr11:106,674,019–107,018,476, 3 genes, copy number 6 (within-gene range 4–6): GUCY1A2, AP001282.2, AP001282.1.
- chr11:107,707,378–107,928,293, 4 genes, copy number 5: SLN, AP002353.1, SLC35F2, AP001024.1.
- chr11:108,105,074–111,347,824, 44 genes, copy number 7–9 (within-gene range 4–9): AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715, RDX, TFAMP2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, MIR4491.
- chr11:112,393,118–121,113,108, 228 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr11:134,274,245–134,763,810, 9 genes, copy number 6: GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.1, LINC02706, LINC02714.
- chr14:21,841,240–26,143,305, 266 genes, copy number 5–6 (broad region; genes not listed).
- chr14:27,612,577–28,613,623, 7 genes, copy number 6 (within-gene range 4–6): LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12.
- chr14:34,659,564–39,432,500, 107 genes, copy number 5–7 (broad region; genes not listed).
- chr14:42,807,378–42,808,112, 1 gene, copy number 5: YWHAQP1.
- chr14:48,319,068–65,102,695, 351 genes, copy number 6–7 (within-gene range 3–10) (broad region; genes not listed).
- chr16:11,555–1,890,434, 162 genes, copy number 5 (broad region; genes not listed).
- chr16:11,741,910–11,926,307, 12 genes, copy number 5 (within-gene range 4–5): AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5 (within-gene range 2–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 2,496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
